Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A2LL, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A2LL-01A (Primary Tumor).

Final Diagnosis

Breast, left, simple mastectomy: Infiltrating pleomorphic lobular carcinoma with focal signet ring cell features, Nottingham grade II (of III) [tubules 3/3, nuclei 2/3, mitoses 1/3; Nottingham score 6/9], forming a mass (9.2 x 4.2 x 3.2 cm) located in the central region of the breast with a separate nodule (0.8 x 0.7 x 0.6 cm) located adjacent to the main mass on the inferior aspect [AJCC pT3]. Lobular carcinoma in situ is present within and outside the invasive component (0.6 cm in greatest dimension). Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows proliferative fibrocystic changes. Calcifications are present in benign ducts and acini. The tumor does not involve the nipple, skin, or underlying chest wall. All surgical resection margins, including the deep margin, are negative for tumor (minimum tumor free margin, 0.4 cm, deep margin).

Sentinel lymph nodes; left axillary Nos. 1, 2, 3, and 4; sentinel biopsy: Multiple (4) left axillary sentinel lymph nodes without blue dye are negative for metastatic carcinoma [AJCC pN0 (i-) (sn)]. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Her-2/Neu has been ordered on paraffin-embedded tissue.

ICB-0-3
Carcinoma, infiltrating (pleomorphic) lobular 8520/3
Site: breast, nos c50.9

on 9/2/11

on 8/18/11

Source: NCI Genomic Data Commons file d3fb9fd0-8c83-4670-aefc-d5d9b5b7ec9f (TCGA-AR-A2LL.B2314041-3E85-4E3F-8924-39FC285B08B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).